Somatic mutation profile of tumor specimen TCGA-A5-A0GQ-01A (aliquot TCGA-A5-A0GQ-01A-11D-A122-09) from TCGA case TCGA-A5-A0GQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 76.9 years (28,078 days).
Specimen TCGA-A5-A0GQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1be6931-b449-434c-b2e0-c4670a893c67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GQ-10A (Blood Derived Normal), aliquot TCGA-A5-A0GQ-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6d2ece9-fc53-4a48-8641-6f360efc3645

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 19, Nonsense Mutation 4, Frame Shift Del 4, In Frame Del 2, Frame Shift Ins 2, RNA 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 27/108 reads (25%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- ESR1 | c.1265_1267del p.V422del | In Frame Del (DEL) | VAF 42/236 reads (18%) | hotspot (GDC flag); called by pindel, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 25/110 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3R1 | c.1351_1356del p.E451_Y452del (on ENST00000521381 / NM_181523.3; = p.E181_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 24/153 reads (16%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PROKR2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138672528, CM083838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABAT | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.066); catalogued as rs776431473, COSV51620565; called by muse, mutect2, varscan2
- ADGRG4 | c.5102C>G p.S1701* | Nonsense Mutation (SNP) | VAF 51/220 reads (23%) | catalogued as COSV54960932; called by muse, mutect2, varscan2
- ANTXR2 | c.1424A>T p.D475V | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56317183; called by muse, mutect2, varscan2
- ARHGAP9 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as rs1479587724, COSV62723548; called by muse, mutect2, varscan2
- ARHGEF11 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63814055; called by muse, mutect2, varscan2
- ARID1A | c.6716T>C p.L2239P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV61374592; called by muse, mutect2, varscan2
- CAMSAP3 | c.3521del p.T1174Sfs*48 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV50339880; called by mutect2, varscan2
- CARMIL1 | c.170C>G p.T57R | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); catalogued as COSV61520144; called by muse, mutect2
- CCDC150 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 34/179 reads (19%) | catalogued as rs1355483344, COSV55876116; called by muse, mutect2, varscan2
- CCDC47 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56723648; called by muse, mutect2, varscan2
- CNTNAP2 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs373383452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.1918G>A p.A640T (on ENST00000520002; = p.A639T on NM_033225.6) | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs779494957, COSV59292435; called by muse, mutect2, varscan2
- CTIF | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1268738342, COSV56486914; called by muse, varscan2
- CYFIP2 | c.3643G>T p.G1215W (on ENST00000616178 / NM_001291722.2; = p.G1190W on NM_014376.4) | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59043978; called by muse, mutect2, varscan2
- CYLC1 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61413713; called by muse, mutect2, varscan2
- CYP4F2 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs146148233, COSV55616274; called by muse, mutect2, varscan2
- E2F4 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62607072; called by muse, mutect2, varscan2
- EZH2 | c.1341C>G p.Y447* (on ENST00000460911 / NM_001203247.2; = p.Y452* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 71/293 reads (24%) | catalogued as COSV57456577; called by muse, mutect2, varscan2
- FAM135B | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52737252; called by muse, mutect2, varscan2
- FGF13 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs201229168, COSV59547071; called by muse, mutect2, varscan2
- GNA11 | c.324C>T p.A108= | Splice Region (SNP) | VAF 8/43 reads (19%) | catalogued as COSV50020885; called by muse, mutect2, varscan2
- HIP1 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61188247; called by muse, mutect2, varscan2
- HR | c.2181C>A p.H727Q | Missense Mutation (SNP) | VAF 102/447 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV57191956, COSV57193252; called by mutect2, varscan2
- ITSN1 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs920288267, COSV66081419; called by muse, mutect2, varscan2
- KCTD10 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.029); catalogued as rs1184350965, COSV57327459; called by muse, mutect2, varscan2
- MAP3K1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68125056; called by muse, mutect2, varscan2
- MARVELD3 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1458856965, COSV51704066, COSV51705229; called by muse, mutect2, varscan2
- MFF | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748018831, COSV58826195; called by muse, mutect2, varscan2
- MUC16 | c.14270C>T p.P4757L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.065); catalogued as COSV67470288, COSV67477700; called by muse, mutect2, varscan2
- NCR1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs759022000, COSV52555719; called by muse, mutect2, varscan2
- NUP210 | c.3739G>A p.V1247I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV54409031; called by muse, mutect2, varscan2
- OR4M1 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 149/702 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.245); catalogued as COSV100271365, COSV60062379; called by muse, mutect2, varscan2
- PCBD1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368664467; called by muse, mutect2, varscan2
- PGR | c.2198C>A p.S733Y | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54805068; called by muse, mutect2, varscan2
- PTEN | c.651del p.C218Afs*3 | Frame Shift Del (DEL) | VAF 69/195 reads (35%) | catalogued as COSV64299647; called by mutect2, pindel, varscan2
- SDSL | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs141271954; called by muse, mutect2, varscan2
- SERHL2 | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59669502; called by mutect2, varscan2
- SLC30A4 | c.1265C>G p.A422G | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56006723; called by muse, mutect2, varscan2
- SLC5A5 | c.1712C>T p.T571I | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV55834054; called by muse, mutect2, varscan2
- STK32C | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866177156, COSV53842452; called by muse, mutect2, varscan2
- SYNGAP1 | c.314del p.S105* | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | catalogued as COSV53383357; called by mutect2, pindel, varscan2
- TRO | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV51504097; called by muse, mutect2, varscan2
- TTN | c.102208C>T p.Q34070* (on ENST00000591111; = p.Q26646* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 37/213 reads (17%) | catalogued as COSV60172211; called by muse, mutect2, varscan2
- XIRP2 | c.5536G>T p.A1846S (on ENST00000628543; = p.A2021S on NM_152381.6) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV54708687; called by muse, mutect2, varscan2
- AKAP9 | c.10278_10279del p.K3428Nfs*3 (on ENST00000359028; = p.K3404Nfs*3 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- CHP2 | c.184dup p.L62Pfs*35 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- MBTPS1 | c.2689_2694dup p.P897_E898dup | In Frame Ins (INS) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.156A>G p.L52= | Silent (SNP) | VAF 62/273 reads (23%) | catalogued as COSV59452199; called by muse, mutect2, varscan2
- DGCR8 | c.1467C>T p.L489= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV61227540, COSV61228039; called by muse, mutect2, varscan2
- DSE | c.1692G>A p.Q564= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV59065376; called by muse, mutect2, varscan2
- DYNC2H1 | c.94C>T p.L32= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV62099036; called by muse, mutect2, varscan2
- EIF3B | c.966C>T p.D322= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs945733263, COSV62803918; called by muse, mutect2, varscan2
- GALNT14 | c.1587C>T p.N529= | Silent (SNP) | VAF 51/204 reads (25%) | catalogued as rs145219116; called by muse, mutect2, varscan2
- IL12RB1 | c.1575G>A p.A525= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1181443900, COSV74045559; called by muse, mutect2, varscan2
- MTREX | c.666A>G p.A222= | Silent (SNP) | VAF 93/408 reads (23%) | catalogued as COSV57927606; called by muse, mutect2, varscan2
- NPSR1 | c.204C>G p.S68= | Silent (SNP) | VAF 122/608 reads (20%) | catalogued as COSV62197604, COSV62203717; called by muse, mutect2, varscan2
- OR4A16 | c.570C>T p.T190= | Silent (SNP) | VAF 80/441 reads (18%) | catalogued as COSV100125096, COSV59043667, COSV59044007; called by muse, mutect2
- OR8D2 | c.411C>A p.S137= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV62488685; called by muse, mutect2, varscan2
- PEX5 | c.972C>T p.Y324= (on ENST00000420616; = p.Y316= on NM_000319.5) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV56956369; called by muse, mutect2
- PLXNA1 | c.3471C>G p.P1157= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV52529008; called by muse, mutect2, varscan2
- SEZ6L | c.1530C>T p.S510= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs147328329; called by muse, mutect2, varscan2
- SYT10 | c.1248G>A p.K416= | Silent (SNP) | VAF 129/611 reads (21%) | catalogued as COSV57342354, COSV57344364; called by muse, mutect2, varscan2
- TAS2R13 | c.411C>G p.T137= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as COSV66831537, COSV66831754; called by muse, mutect2, varscan2
- TTN | c.44316C>A p.T14772= (on ENST00000591111; = p.T7348= on NM_003319.4) | Silent (SNP) | VAF 107/514 reads (21%) | catalogued as COSV60172240; called by muse, mutect2, varscan2
- ZC3H7B | c.2661C>T p.G887= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV60963111; called by muse, mutect2, varscan2
- ZNF606 | c.1218G>T p.G406= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as COSV58706867; called by muse, mutect2, varscan2
- SSPOP | n.1534C>T | RNA (SNP) | VAF 18/82 reads (22%) | catalogued as rs774529050, COSV50487313; called by muse, varscan2
